Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4J5, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4J5-01A (Primary Tumor).

Gross Description: In lesser curvature-antrum, there is a large ulcerated tumor with 3x4x1.5cm in size, firm and myxoid gray surface.

Microscopic Description: Mucosa is ulcerated. The tumor is composed of large pools of extracellular mucin that contain malignant epithelium as cord or acinar or adenoid structures or signet ring cells. Tumor in invasion in serosa. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present.

Diagnosis Details: Mucinous Adenocarcinoma, infiltrating serosa.

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 3 x 4 x 1.5 cm

Tumor features: Ulcerated

Histologic type: Mucinous adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 1/5 positive for metastasis (Adjacent lymph node 1/5)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

1C4-0-3

adenocarcinoma, mucinous, NOS 8480/3

Site: stomach, antrum C16.3

hw
10/2/12

hw

Source: NCI Genomic Data Commons file b0963bab-0558-4b0e-8eba-c5228a115a1c (TCGA-BR-A4J5.A42D8979-68E8-4DF3-B446-1A3EB7AE6226.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).